Somatic mutation profile of tumor specimen 0DB32I from CCDI case PBBKUP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.0 years (2,937 days).
Specimen 0DB32I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d992e2a-4738-4604-9f79-dd47ac269d52.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DB32H (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c61d4d91-affb-4160-90ec-52f6ce332e98

The open-access MAF lists 15 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 5, 3'UTR 4, Missense Mutation 4, 5'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 189/1629 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CEP120 | c.1048G>C p.E350Q | Missense Mutation (SNP) | VAF 26/758 reads (3%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- COL6A6 | c.2587C>G p.L863V | Missense Mutation (SNP) | VAF 34/789 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PRKG1 | c.733C>A p.L245I | Missense Mutation (SNP) | VAF 45/1462 reads (3%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.541); called by muse, mutect2
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 18/383 reads (5%) | catalogued as rs1167537044; called by muse, mutect2
- AC005833.1 | c.*83A>T | 3'UTR (SNP) | VAF 16/131 reads (12%) | called by muse, varscan2
- AKR7L | c.215-53T>C | Intron (SNP) | VAF 16/200 reads (8%) | catalogued as COSV70167427; called by muse, mutect2
- BPNT1 | c.*35T>C | 3'UTR (SNP) | VAF 28/450 reads (6%) | catalogued as rs1372238489, COSV59039295; called by muse, mutect2
- COLEC11 | c.-26-728A>G | Intron (SNP) | VAF 35/501 reads (7%) | called by muse, mutect2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 14/120 reads (12%) | called by muse, varscan2
- OR2AP1 | c.*96A>G | 3'UTR (SNP) | VAF 11/89 reads (12%) | catalogued as rs1012935800, COSV58726711; called by muse, mutect2
- PTCH1 | c.3449+89A>G | Intron (SNP) | VAF 22/256 reads (9%) | catalogued as COSV100109080; called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 30/257 reads (12%) | called by muse, varscan2
- TMEM178B | c.*33A>T | 3'UTR (SNP) | VAF 35/346 reads (10%) | catalogued as rs1434668436; called by muse, varscan2
- YAF2 | c.152+26951G>T | Intron (SNP) | VAF 32/718 reads (4%) | catalogued as rs1041371904, COSV100586253; called by muse, mutect2
